Somatic mutation profile of tumor specimen TCGA-EP-A3RK-01A (aliquot TCGA-EP-A3RK-01A-11D-A22F-10) from TCGA case TCGA-EP-A3RK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.9 years (26,985 days).
Specimen TCGA-EP-A3RK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c05450-f235-4fa8-8949-90505a6dc81e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A3RK-10A (Blood Derived Normal), aliquot TCGA-EP-A3RK-10A-01D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4205544e-6ea2-48fc-99cd-6ec657698bc3

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Ins 3, Nonsense Mutation 2, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 30/168 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- ACTR1B | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56703902; called by mutect2, varscan2
- ALPK2 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV64492126; called by muse, mutect2, varscan2
- ARAP2 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as COSV58285456; called by muse, mutect2, varscan2
- ARHGEF4 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1334913907, COSV58120804; called by muse, mutect2, varscan2
- ASPM | c.3152T>C p.I1051T | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54128281; called by muse, mutect2
- ATRNL1 | c.2823A>T p.Q941H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58083018; called by muse, mutect2, varscan2
- BATF2 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57249779; called by muse, mutect2, varscan2
- BCR | c.3502C>G p.L1168V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV59929680; called by muse, mutect2, varscan2
- BRPF1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57404287; called by muse, mutect2, varscan2
- BSCL2 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs144725547; called by muse, mutect2, varscan2
- CACNG2 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.95); catalogued as COSV55634008; called by muse, mutect2, varscan2
- CHML | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as COSV59363606; called by muse, mutect2, varscan2
- COBL | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs566661748, COSV54343208, COSV99474100; called by muse, mutect2, varscan2
- FANCI | c.2993C>T p.P998L (on ENST00000310775 / NM_001376911.1; = p.P938L on NM_018193.3) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55525719; called by muse, mutect2, varscan2
- GLIS1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56547197; called by muse, mutect2, varscan2
- GMIP | c.1905C>G p.I635M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV52555496; called by muse, mutect2
- GREB1 | c.2209C>G p.Q737E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV52184750; called by muse, mutect2, varscan2
- HEY1 | c.170T>G p.I57S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61232743; called by muse, mutect2, varscan2
- IL18RAP | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV51825354; called by muse, mutect2, varscan2
- IL2RB | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1415121012, COSV53425901; called by muse, mutect2, varscan2
- KIF1C | c.1771A>G p.K591E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV57904046; called by muse, mutect2, varscan2
- L3MBTL3 | c.2156G>C p.S719T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.241); catalogued as COSV62385501; called by muse, mutect2, varscan2
- MRPS24 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs763480703, COSV58182225; called by muse, mutect2, varscan2
- MYBPC3 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV57025981; called by muse, mutect2
- NAGA | c.1134T>A p.S378R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV67169886; called by muse, mutect2, varscan2
- NLRX1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs548995927, COSV52703440; called by muse, mutect2, varscan2
- NPY2R | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61527854; called by muse, mutect2, varscan2
- NUDT11 | c.483T>G p.D161E | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV65665091; called by muse, mutect2, varscan2
- PALMD | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV54163990; called by muse, mutect2, varscan2
- PDE6A | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774005137, COSV54926442; called by muse, mutect2, varscan2
- PER2 | c.2951G>T p.R984L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54522932, COSV54527103; called by muse, mutect2, varscan2
- PLA2G4A | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66553306; called by muse, mutect2, varscan2
- PREX1 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441531948, COSV64250584; called by muse, mutect2, varscan2
- PTPRT | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV61974653; called by muse, mutect2, varscan2
- PYGM | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs746412712, COSV51215962, COSV51226028; called by muse, mutect2, varscan2
- SCN5A | c.4445G>T p.G1482V (on ENST00000333535 / NM_198056.3; = p.G1481V on NM_000335.5) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61121394; called by muse, mutect2, varscan2
- SEMA3A | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV54867348, COSV54874744; called by muse, mutect2, varscan2
- SLIT1 | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV56587189; called by muse, mutect2, varscan2
- SPEG | c.2449A>G p.T817A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV56666954; called by muse, mutect2, varscan2
- SPTAN1 | c.5972G>T p.W1991L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63986492; called by muse, mutect2
- TBC1D7 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV58243685, COSV58243785; called by muse, mutect2
- TBCCD1 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV58661893; called by muse, mutect2, varscan2
- TMED7 | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs960731200, COSV56695100; called by muse, mutect2, varscan2
- UBR2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65749761; called by muse, mutect2, varscan2
- ACVR2A | c.1310dup p.R438Efs*19 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- AGK | c.643A>T p.R215* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- NCOR2 | c.3815dup p.K1273Qfs*9 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SDS | c.635_636insA p.L213Pfs*32 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ADCY8 | c.2517G>T p.T839= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs755447347, COSV53903927; called by muse, mutect2, varscan2
- ANKFY1 | c.1353C>T p.D451= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs745878528, COSV58916641; called by mutect2, varscan2
- ATAD2B | c.4011T>C p.C1337= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as COSV53197283; called by muse, mutect2, varscan2
- C9orf64 | c.168C>T p.N56= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs560017514, COSV59032398; called by muse, mutect2, varscan2
- DDX46 | c.2538T>A p.A846= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV62799048; called by muse, mutect2, varscan2
- DGUOK | c.738A>G p.P246= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV51203430; called by muse, mutect2, varscan2
- KCP | c.4074C>T p.R1358= (on ENST00000620378; = p.R1482= on NM_001366122.1) | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV52821450, COSV99926283; called by muse, mutect2, varscan2
- MMP2 | c.387T>A p.I129= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV54600509; called by muse, mutect2, varscan2
- NFATC4 | c.1695C>A p.V565= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV51600022, COSV99151200; called by muse, mutect2, varscan2
- POTEE | c.732C>T p.H244= | Silent (SNP) | VAF 103/611 reads (17%) | catalogued as COSV100387363; called by muse, mutect2, varscan2
- PPP5C | c.1113G>A p.R371= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV50139749; called by muse, mutect2, varscan2
- RB1CC1 | c.4782A>G p.V1594= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs145350535; called by muse, mutect2, varscan2
- SERPINA3 | c.69C>T p.C23= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1303905509, COSV101261648; called by muse, mutect2
- ZNF665 | c.222T>C p.N74= (on ENST00000600412; = p.N139= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs751461693, COSV67214490; called by muse, mutect2, varscan2
- ZNF677 | c.159T>A p.P53= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV61720035; called by muse, mutect2, varscan2
- PPFIA4 | c.2782-28C>T | Intron (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-25471C>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs1340205836, COSV66067517; called by muse, mutect2
